Somatic mutation profile of tumor specimen MMRF_2579_1_BM_CD138pos (aliquot MMRF_2579_1_BM_CD138pos_T1_KHS5U_K15214) from MMRF case MMRF_2579, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.8 years (22,560 days).
Specimen MMRF_2579_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae21e0fc-b882-4427-a470-10cb9fcfb807.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2579_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2579_1_PB_Whole_C3_KHS5U_K15215; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa8d76c9-1e7e-4aa1-8150-5cf03e0357df

The open-access MAF lists 62 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 21, Missense Mutation 17, Intron 8, Silent 5, 5'UTR 4, In Frame Del 2, 5'Flank 2, Nonsense Mutation 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ASXL2 | c.3519T>G p.S1173R | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.386); catalogued as rs762088026; called by muse, mutect2, varscan2
- CILP2 | c.3083G>A p.R1028Q | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs929120124, COSV99364469; called by muse, mutect2, varscan2
- DUSP2 | c.378C>G p.Y126* | Nonsense Mutation (SNP) | VAF 63/133 reads (47%) | catalogued as rs1364514451, COSV56619695; called by muse, mutect2, varscan2
- ETV3 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as COSV63864960; called by muse, mutect2, varscan2
- FZR1 | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 25/399 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs972459532; called by muse, mutect2
- IGLV3-1 | c.181T>C p.S61P | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs762596366; called by muse, varscan2
- IRX6 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 99/203 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs760982735; called by muse, mutect2, varscan2
- LTBP4 | c.3268G>A p.V1090M (on ENST00000308370 / NM_001042544.1; = p.V1053M on NM_003573.2) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as rs559351690, COSV52580549; called by muse, mutect2, varscan2
- SOGA1 | c.2685_2687del p.K895del | In Frame Del (DEL) | VAF 63/190 reads (33%) | catalogued as rs752763781; called by pindel, varscan2
- SUPT3H | c.431G>C p.R144T (on ENST00000371460 / NM_181356.3; = p.R133T on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60940406; called by muse, mutect2, varscan2
- ANK2 | c.4426dup p.N1476Kfs*2 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | called by mutect2, pindel
- BTNL8 | c.1133G>T p.W378L | Missense Mutation (SNP) | VAF 95/329 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DIS3 | c.1559A>T p.D520V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIS3 | c.593T>G p.V198G | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- MAGI1 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MTREX | c.343G>C p.A115P | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- MYO7B | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PCTP | c.339+3A>T | Splice Region (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- PGM1 | c.1435C>G p.P479A | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- RYBP | c.211_213del p.K71del | In Frame Del (DEL) | VAF 38/116 reads (33%) | called by pindel, varscan2
- SHANK3 | c.4628G>A p.R1543H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- GDF5 | c.534G>A p.R178= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as rs1485489611; called by muse, mutect2, varscan2
- ITGA1 | c.2886A>T p.S962= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as rs919310865; called by muse, mutect2, varscan2
- MED23 | c.2622C>T p.H874= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as rs372819523; called by muse, mutect2, varscan2
- PTPN14 | c.1767C>T p.Y589= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as rs375699206; called by muse, mutect2, varscan2
- RGS22 | c.1923T>C p.Y641= | Silent (SNP) | VAF 93/217 reads (43%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.*2609G>T | 3'UTR (SNP) | VAF 21/111 reads (19%) | called by muse, mutect2, varscan2
- ATG13 | c.*2109C>G | 3'UTR (SNP) | VAF 15/205 reads (7%) | called by muse, mutect2
- CEP126 | c.507-1417C>A | Intron (SNP) | VAF 166/571 reads (29%) | called by muse, mutect2, varscan2
- CNNM1 | c.*1277C>G | 3'UTR (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- COA8 | c.123+149C>T | Intron (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- CSK | c.*604G>A | 3'UTR (SNP) | VAF 89/208 reads (43%) | called by muse, mutect2, varscan2
- DCBLD2 | c.-36C>T | 5'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- EARS2 | c.*51G>C | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- EIF2S3B | chr12:10505883 del T | 5'Flank (DEL) | VAF 46/95 reads (48%) | called by mutect2, pindel, varscan2
- EPHA5 | c.*3309G>C | 3'UTR (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- FBLIM1 | c.*353G>A | 3'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- FSD2 | c.*3084G>T | 3'UTR (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- GJB2 | c.-20C>G | 5'UTR (SNP) | VAF 25/28 reads (89%) | called by muse, mutect2, varscan2
- GPA33 | c.*992C>T | 3'UTR (SNP) | VAF 40/91 reads (44%) | catalogued as rs1434394036; called by muse, mutect2, varscan2
- IGHV6-1 | c.-8T>G | 5'UTR (SNP) | VAF 21/22 reads (95%) | called by muse, varscan2
- ILRUN | c.*3051G>C | 3'UTR (SNP) | VAF 53/124 reads (43%) | called by muse, mutect2, varscan2
- KIAA0895 | c.*2142T>A | 3'UTR (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- LMBR1L | c.72+710G>C | Intron (SNP) | VAF 64/126 reads (51%) | catalogued as rs932165564; called by muse, mutect2, varscan2
- LRRC27 | c.926+698G>A | Intron (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
- LVRN | c.2757-829T>G | Intron (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
- MTMR6 | c.*1364G>T | 3'UTR (SNP) | VAF 67/74 reads (91%) | called by muse, mutect2, varscan2
- PLXNA3 | c.*753G>A | 3'UTR (SNP) | VAF 13/192 reads (7%) | called by muse, mutect2
- PSAP | c.*1007dup | 3'UTR (INS) | VAF 149/397 reads (38%) | called by mutect2, pindel, varscan2
- PTPRM | c.*48G>A | 3'UTR (SNP) | VAF 127/396 reads (32%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.*553G>T | 3'UTR (SNP) | VAF 68/146 reads (47%) | called by muse, varscan2
- RBM44 | c.15-91G>T | Intron (SNP) | VAF 8/27 reads (30%) | catalogued as COSV57629805; called by muse, mutect2, varscan2
- SENP5 | c.*2986T>A | 3'UTR (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- SH3GLB2 | c.*207C>G | Intron (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- SLC22A2 | c.1065-451T>C | Intron (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- SLC3A2 | chr11:62853360 T>G | 5'Flank (SNP) | VAF 42/146 reads (29%) | called by muse, mutect2, varscan2
- STYK1 | c.*1151_*1156del | 3'UTR (DEL) | VAF 30/77 reads (39%) | called by mutect2, pindel, varscan2
- TBCD | c.*155C>A | 3'UTR (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- TIMMDC1 | c.-110T>G | 5'UTR (SNP) | VAF 121/278 reads (44%) | called by muse, mutect2, varscan2
- VIPR1 | c.*846C>T | 3'UTR (SNP) | VAF 88/259 reads (34%) | called by muse, mutect2, varscan2
- WDR12 | c.*118A>C | 3'UTR (SNP) | VAF 50/104 reads (48%) | called by muse, mutect2, varscan2
